Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6YV, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6YV-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

ICD-O-3
Myxofibrosarcoma 8811/3
Site Rt thigh NOS C49.2
JW 8/9/13

....

Clinical Diagnosis & History:

[REDACTED] with history of right thigh mass biopsy demonstrated high grade pleomorphic sarcoma consistent with increased FH. Here for wide excision. High grade pleomorphic sarcoma.

Specimens Submitted:

1: SP: Right thigh mass

Per TSS, tumor was reclassified from
pleomorphic sarcoma (diopsy) to
myxofibrosarcoma upon tumor resection
BCR

DIAGNOSIS:

1. SOFT TISSUE, RIGHT THIGH MASS, EXCISION:
- HIGH GRADE MYXOFIBROSARCOMA, INVOLVING THE SKELETAL MUSCLE
- TUMOR SHOWS EXTENSIVE NECROSIS (30-40% GROSS ESTIMATE).
- TUMOR SIZE: 19 X 14 X 11 CM.
- THE MARGINS OF RESECTION ARE FREE OF TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh labeled "right thigh mass" and consists of skin measuring 7 x 2.5 cm with an underlying mass measuring 19 x 14 x 11 cm and weighing 1420 gm. A black suture marks the anterior margin, and a white suture marks the distal margin. The specimen is inked as follows: (yellow distal, red proximal, blue anterior, green posterior and black deep). Cross-sectioning reveals that the mass is tan light brown and soft with hemorrhagic and necrotic areas with cystic degeneration (30-40% necrosis). The tumor is located within the skeletal muscle. The margins grossly are free of tumor. TPS is submitted, a picture is taken and representative sections are submitted.

Summary sections:

DEEP-deep margin

** Continued on next page **

[page 2 of 2]
DM-distal margin
PRM-proximal margin
AM-anterior margin
POM-posterior margin
SK-skin
R-tumor representative

Summary of Sections:
Part 1: SP: Right thigh mass

Block	Sect.	Site	PCs	
1		{not entered}		1
1	AM		1	
2	DEEP		2	
1	DM		1	
1	POM		1	
1	PRM		1	
8	R		8	
1	SK		1	

** End of Report **

IIPA's Discrepancy		☒
Qual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file 91ea6da4-01d8-4b70-bd5e-09324039862e (TCGA-DX-A6YV.26FE2F1A-3C57-43AD-8298-D6D24AC6183B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).